Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4869, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4869-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY, RADICAL NEPHRECTOMY AND LIVER EDGE:

CONVENTIONAL RENAL CELL CARCINOMA (GRANULAR CELL 70%, CLEAR CELL 30%), FUHRMAN'S
NUCLEAR GRADE 3.

TUMOR MEASURES 8.5 CM IN GREATEST DIMENSION.

FOCAL LYMPHATIC/VASCULAR INVASION IDENTIFIED.

No extension into perinephric adipose tissue identified.

Margins of resection free of tumor.

Adrenal gland, no tumor present.

Segment of liver, no tumor present.

(B) GALLBLADDER, CHOLECYSTECTOMY:

MILD CHRONIC INFLAMMATION.

CHOLELITHIASIS.

(C) SUPERFICIAL INTER-AORTOCAVAL LYMPH NODES:

Five lymph nodes, no tumor present.

(D) DEEP INTER-AORTOCAVAL AND RIGHT PARACAVAL LYMPH NODES:

METASTATIC RENAL CELL CARCINOMA IN TWO OF NINE LYMPH NODES.

LARGEST TUMOR FOCUS MEASURES 1.5 CM IN GREATEST DIMENSION.

(E) PARA-AORTIC LYMPH NODES:

One lymph node, no tumor present.

Source: NCI Genomic Data Commons file 778bb2dc-afd2-4cf1-84b2-367ad2317424 (TCGA-CJ-4869.9F1CBBDD-187D-44AA-86B6-57B79917DB41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).